Somatic mutation profile of tumor specimen 6f5853a3-1d47-4a54-94dc-970c1c (aliquot 6f5853a3-1d47-4a54-94dc-970c1c_D6_1) from CPTAC case 16CO002, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 6f5853a3-1d47-4a54-94dc-970c1c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd8dbf2a-03ef-4c88-b44d-2b98ccac25a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f96ed690-876c-4dc1-a919-025154 (Blood Derived Normal), aliquot f96ed690-876c-4dc1-a919-025154_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/225d1f1a-2bac-4409-bc12-5c44a50fb5d5

The open-access MAF lists 95 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 24, Intron 8, Nonsense Mutation 4, 3'UTR 3, Frame Shift Del 2, 5'Flank 2, Splice Site 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK5 | c.463C>T p.R155* (on ENST00000354567 / NM_174858.3; = p.R129* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as rs769178688; called by mutect2, varscan2
- ATXN1 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55222955; called by mutect2, varscan2
- C6 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.607); catalogued as rs143839537, COSV54710168, COSV54721144; called by muse, mutect2, varscan2
- CCDC85A | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV68148474; called by muse, mutect2, varscan2
- CLDN8 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs893943148, COSV54525776; called by muse, mutect2, varscan2
- CMYA5 | c.2378C>A p.P793Q | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV71405373; called by mutect2, varscan2
- COL6A3 | c.5909G>A p.R1970H | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.719); catalogued as rs368635334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA4 | c.60A>T p.K20N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV55978613, COSV55978975; called by muse, mutect2, varscan2
- DIP2A | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs543799829; called by muse, varscan2
- DNAH17 | c.8435G>A p.R2812H | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778772093; called by muse, mutect2, varscan2
- DNASE2 | c.925G>T p.V309L | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV52246608, COSV99262413, COSV99263955; called by muse, mutect2, varscan2
- FRRS1L | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs753180568; called by muse, mutect2, varscan2
- FRY | c.8858G>A p.R2953H | Missense Mutation (SNP) | VAF 94/368 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs141662577; called by muse, mutect2, varscan2
- GRM8 | c.144G>T p.L48F | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV100282977, COSV58820098; called by mutect2, varscan2
- HOXA5 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56075084; called by muse, mutect2, varscan2
- KLF5 | c.919T>G p.S307A | Missense Mutation (SNP) | VAF 186/381 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66615648; called by muse, mutect2, varscan2
- LCT | c.4996_4997del p.S1666* | Frame Shift Del (DEL) | VAF 53/376 reads (14%) | catalogued as rs1398217038; called by pindel, varscan2
- MCPH1 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs376110995; called by muse, mutect2, varscan2
- NRG3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1449934073, CM133993, COSV64554737, COSV64590310; called by muse, mutect2, varscan2
- NRK | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs764122599; called by muse, mutect2, varscan2
- PICALM | c.1382G>T p.R461M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as rs778441424; called by mutect2, varscan2
- PRSS36 | c.272+1G>A p.X91_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as rs757687217; called by muse, mutect2, varscan2
- RREB1 | c.4378G>A p.G1460R | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs751620301; called by muse, mutect2, varscan2
- SHANK1 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV53255058; called by muse, mutect2, varscan2
- SOX9 | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 130/306 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1407667250, COSV55422286; called by muse, mutect2, varscan2
- TET1 | c.4549G>A p.V1517M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs1169034139; called by muse, mutect2, varscan2
- TIAM2 | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs751322089, COSV99265427; called by muse, mutect2, varscan2
- TRPV2 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs759477903; called by muse, mutect2, varscan2
- VSIG10L | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018134824; called by muse, mutect2, varscan2
- VTCN1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as rs374822982; called by muse, mutect2, varscan2
- ZNF626 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201387631, COSV74129883; called by mutect2, varscan2
- ATG10 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CARTPT | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 90/484 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CPNE1 | c.712C>A p.P238T (on ENST00000352393; = p.P243T on NM_003915.5) | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DENND2C | c.1172G>A p.W391* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- DNAI2 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 147/303 reads (49%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HMCN1 | c.3802G>T p.E1268* | Nonsense Mutation (SNP) | VAF 43/331 reads (13%) | called by muse, mutect2, varscan2
- ICAM5 | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ILDR2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- L1TD1 | c.2147G>A p.R716K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LEO1 | c.1847A>C p.E616A | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- LRPPRC | c.3451A>G p.M1151V | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LUZP1 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MORC1 | c.1267T>A p.Y423N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NEB | c.6422T>C p.I2141T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NFRKB | c.637G>T p.E213* (on ENST00000446488 / NM_001143835.2; = p.E226* on NM_006165.3) | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | called by mutect2, varscan2
- NIBAN3 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- POTEG | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- RARB | c.1171+3_1171+9del p.X391_splice (on ENST00000383772 / NM_001290216.2; = p.X384_splice on NM_000965.5 and 3 other RefSeq transcripts) | Splice Site (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- RGMB | c.593A>C p.Q198P (on ENST00000513185 / NM_001366508.1; = p.Q239P on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN11A | c.2125G>A p.V709I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by mutect2, varscan2
- SLC15A5 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TCF7 | c.1026+4_1026+5del | Splice Region (DEL) | VAF 36/181 reads (20%) | called by mutect2, pindel, varscan2
- TET1 | c.3227A>C p.D1076A | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TMEM174 | c.365del p.F122Sfs*31 | Frame Shift Del (DEL) | VAF 162/558 reads (29%) | called by mutect2, pindel, varscan2
- WDR64 | c.1446G>T p.W482C | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH3A1 | c.1110C>T p.N370= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs374241489; called by muse, mutect2, varscan2
- C16orf71 | c.714G>A p.A238= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs369881957; called by muse, mutect2, varscan2
- FBXW12 | c.948A>G p.L316= | Silent (SNP) | VAF 67/232 reads (29%) | called by muse, mutect2, varscan2
- GATA3 | c.87G>A p.P29= | Silent (SNP) | VAF 24/344 reads (7%) | catalogued as rs1172035480, COSV100650993; called by muse, mutect2
- GCM2 | c.9G>A p.A3= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as COSV65275735; called by muse, mutect2, varscan2
- GEM | c.789C>T p.P263= | Silent (SNP) | VAF 198/400 reads (50%) | called by muse, mutect2, varscan2
- GPRIN1 | c.1176G>T p.T392= | Silent (SNP) | VAF 47/233 reads (20%) | catalogued as COSV99992018; called by muse, mutect2, varscan2
- KIAA1549 | c.5310C>T p.P1770= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2
- KMT2E | c.2031C>A p.I677= | Silent (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- LDHD | c.609G>A p.A203= | Silent (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- METTL21C | c.303C>T p.Y101= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- MYH13 | c.1545C>T p.F515= | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as rs369290557; called by muse, mutect2, varscan2
- MYLK3 | c.1962C>A p.I654= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- OR10G4 | c.9C>T p.N3= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as rs547870, COSV57978291; called by mutect2, varscan2
- PCDHGA2 | c.1887G>A p.A629= | Silent (SNP) | VAF 111/628 reads (18%) | catalogued as COSV53910951; called by muse, mutect2, varscan2
- PPP1R3A | c.714G>A p.P238= | Silent (SNP) | VAF 42/209 reads (20%) | catalogued as rs557887098, COSV99493051; called by muse, mutect2, varscan2
- SPATA18 | c.1260C>T p.I420= | Silent (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- TECTA | c.5907C>T p.D1969= | Silent (SNP) | VAF 78/347 reads (22%) | catalogued as rs1327655190; called by muse, mutect2, varscan2
- TLN2 | c.3174G>A p.T1058= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs554839999; called by muse, mutect2, varscan2
- TRAF5 | c.786A>G p.E262= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- UNC5B | c.1638C>T p.S546= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as rs374710244; called by muse, mutect2, varscan2
- UTS2 | c.120G>A p.A40= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs759501467, COSV50013627; called by muse, mutect2, varscan2
- ZNF792 | c.711G>C p.P237= | Silent (SNP) | VAF 58/342 reads (17%) | called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.195C>A p.I65= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- APP | c.*5C>T | 3'UTR (SNP) | VAF 31/174 reads (18%) | catalogued as rs745519536; called by muse, mutect2, varscan2
- IFI44L | c.723+100A>C | Intron (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- LARS2 | c.*134A>G | 3'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- MAZ | c.1280-362C>T | Intron (SNP) | VAF 26/85 reads (31%) | catalogued as rs1339500286; called by muse, mutect2, varscan2
- NRBF2P6 | n.393G>A | RNA (SNP) | VAF 28/160 reads (18%) | catalogued as rs763025879; called by muse, mutect2, varscan2
- OAZ3 | c.480-59G>A | Intron (SNP) | VAF 13/93 reads (14%) | catalogued as rs1457816759; called by muse, mutect2, varscan2
- OBSCN | c.11660-2610C>T | Intron (SNP) | VAF 36/248 reads (15%) | catalogued as rs755764610; called by muse, mutect2, varscan2
- RAB17 | chr2:237594954 del C | 5'Flank (DEL) | VAF 16/96 reads (17%) | catalogued as rs747781654; called by pindel, varscan2
- RPL37A | c.133-86_133-84del | Intron (DEL) | VAF 56/143 reads (39%) | catalogued as rs751900040; called by mutect2, pindel, varscan2
- RPS6KB1 | c.*784C>A | 3'UTR (SNP) | VAF 23/31 reads (74%) | called by muse, mutect2, varscan2
- UBAP2L | c.2902+1408A>C | Intron (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- VWA3B | c.1115-1705C>T | Intron (SNP) | VAF 47/177 reads (27%) | catalogued as rs778422520; called by muse, mutect2
- ZKSCAN8 | chr6:28136946 G>A | 5'Flank (SNP) | VAF 12/147 reads (8%) | called by muse, mutect2
- ZNF668 | c.-22-161G>A | Intron (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
